Somatic mutation profile of tumor specimen TCGA-WK-A8XX-01A (aliquot TCGA-WK-A8XX-01A-11D-A37C-09) from TCGA case TCGA-WK-A8XX, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 70.4 years (25,701 days).
Specimen TCGA-WK-A8XX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 10d1b38e-5aa9-46b6-808c-b2f5fe531083.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WK-A8XX-10A (Blood Derived Normal), aliquot TCGA-WK-A8XX-10A-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/414e8c7b-dcb1-400b-a38a-2935cba8ffe5

The open-access MAF lists 46 somatic variants for this specimen: 35 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 31, Silent 11, Nonsense Mutation 1, Splice Site 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.776A>T p.D259V | Missense Mutation (SNP) | VAF 21/30 reads (70%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as rs745425759, COSV52677009, COSV52679505, COSV53544033; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AP3D1 | c.2137T>A p.L713M | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100642713; called by muse, mutect2, varscan2
- ATP10B | c.4020C>A p.D1340E | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100515084; called by muse, mutect2, varscan2
- CFAP57 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs368874977; called by muse, mutect2, varscan2
- CHL1 | c.1977G>T p.W659C (on ENST00000397491 / NM_001253387.1; = p.W675C on NM_006614.4) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99851346; called by muse, mutect2, varscan2
- CLPTM1 | c.434G>T p.C145F | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.647); catalogued as COSV100493787; called by muse, mutect2
- CNR1 | c.742G>T p.A248S | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.297); catalogued as COSV100759232, COSV62986936; called by muse, mutect2, varscan2
- CNTN6 | c.1238G>C p.S413T | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.111); catalogued as COSV100610794; called by muse, mutect2, varscan2
- COL23A1 | c.882+2T>A p.X294_splice | Splice Site (SNP) | VAF 24/79 reads (30%) | catalogued as COSV101178930; called by muse, mutect2, varscan2
- DLGAP2 | c.2561A>C p.D854A | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.281); catalogued as COSV101422011; called by muse, mutect2, varscan2
- ELAVL3 | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.398); catalogued as rs148057857; called by muse, mutect2, varscan2
- EXOSC4 | c.364G>C p.D122H | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100284082; called by muse, mutect2
- FGB | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV100122451; called by muse, mutect2, varscan2
- GIMAP8 | c.1932T>G p.I644M | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as COSV100217548; called by muse, mutect2, varscan2
- IL2RB | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.539); catalogued as rs768345015, COSV53426180; called by muse, mutect2, varscan2
- KIAA1958 | c.778A>T p.I260F | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.054); catalogued as rs760276121, COSV100516128; called by muse, varscan2
- KLKB1 | c.728A>T p.Y243F | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (1); PolyPhen possibly damaging (0.877); catalogued as COSV52994826; called by muse, mutect2, varscan2
- MET | c.2087C>T p.T696I | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.702); catalogued as rs750276956, COSV100577238; called by muse, mutect2, varscan2
- NRF1 | c.283C>T p.H95Y | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.615); catalogued as COSV99781827; called by muse, mutect2, varscan2
- PCDHB1 | c.2224C>A p.Q742K | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV60632456; called by muse, mutect2, varscan2
- PCNX2 | c.6206G>A p.G2069D | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99267869; called by muse, mutect2, varscan2
- PLEKHA1 | c.635A>G p.Y212C | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64569596; called by muse, mutect2, varscan2
- RANBP2 | c.1624A>G p.K542E | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as COSV99312227; called by muse, mutect2, varscan2
- RBBP6 | c.4951T>A p.S1651T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV100154622; called by muse, mutect2, varscan2
- RBFOX1 | c.105C>A p.N35K | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs542828240, COSV100300124; called by muse, mutect2, varscan2
- SMARCAL1 | c.2143G>T p.E715* | Nonsense Mutation (SNP) | VAF 4/9 reads (44%) | catalogued as COSV100619901; called by muse, mutect2, varscan2
- VEPH1 | c.921C>A p.S307R | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.08); catalogued as COSV100747605; called by muse, mutect2
- WDHD1 | c.146A>T p.K49M | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100864352; called by muse, mutect2, varscan2
- ZAN | c.908T>C p.L303P | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100769768; called by muse, mutect2, varscan2
- ZFYVE9 | c.2762A>G p.E921G | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV99820076; called by muse, mutect2, varscan2
- ZNF629 | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs750197596, COSV99354819; called by muse, mutect2, varscan2
- IGHJ2 | c.44T>G p.V15G | Missense Mutation (SNP) | VAF 6/38 reads (16%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NFAT5 | c.4434_4451del p.Q1480_P1485del | In Frame Del (DEL) | VAF 7/29 reads (24%) | called by mutect2, pindel, varscan2
- PIAS1 | c.1285del p.Y429Tfs*8 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | called by mutect2, pindel, varscan2
- WWC1 | c.560T>A p.F187Y | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- CYP11B2 | c.1228C>T p.L410= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV100011060; called by muse, mutect2, varscan2
- EDF1 | c.34C>T p.L12= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV99808058; called by muse, mutect2, varscan2
- EGF | c.3243C>T p.R1081= | Silent (SNP) | VAF 25/51 reads (49%) | catalogued as rs1488123532, COSV99490739; called by muse, mutect2, varscan2
- FOXK1 | c.510G>T p.V170= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV100195259; called by muse, mutect2, varscan2
- GAA | c.1833C>T p.G611= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as CX064756, COSV100163235; called by muse, mutect2, varscan2
- GIMAP6 | c.381C>G p.L127= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV100188249, COSV100188305, COSV100188314; called by muse, varscan2
- MACF1 | c.6156G>A p.Q2052= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV99244642; called by muse, mutect2, varscan2
- MYH2 | c.2322T>C p.G774= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV99820243; called by muse, mutect2, varscan2
- PARVB | c.747C>T p.A249= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV100114884; called by muse, mutect2, varscan2
- PRKDC | c.531C>T p.L177= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as COSV100040807; called by muse, mutect2
- TSHZ3 | c.1309C>T p.L437= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV53679061; called by muse, mutect2, varscan2
